Somatic mutation profile of tumor specimen TCGA-HU-A4H5-01A (aliquot TCGA-HU-A4H5-01A-21D-A25D-08) from TCGA case TCGA-HU-A4H5, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: GX; Age at diagnosis: 71.8 years (26,232 days).
Specimen TCGA-HU-A4H5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b56607a-7763-4307-b1a0-42e23bfb4831.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4H5-11A (Solid Tissue Normal), aliquot TCGA-HU-A4H5-11A-11D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d37514ff-9795-4b3c-8920-d413ddaaf1e2

The open-access MAF lists 297 somatic variants for this specimen: 235 protein-altering or splice-affecting, 56 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 191, Silent 56, Nonsense Mutation 15, Frame Shift Del 10, In Frame Del 9, Splice Site 8, Intron 2, RNA 2, 5'Flank 1, 3'UTR 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 26/55 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.2298G>T p.K766N (on ENST00000614293; = p.K736N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV55798002; called by muse, mutect2, varscan2
- ABCA8 | c.509C>G p.S170* | Nonsense Mutation (SNP) | VAF 31/183 reads (17%) | catalogued as COSV52195216; called by muse, mutect2, varscan2
- ABLIM3 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as rs138587496; called by muse, mutect2, varscan2
- ACRV1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 98/127 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV59754567; called by muse, mutect2, varscan2
- ACSS3 | c.1820-1G>C p.X607_splice | Splice Site (SNP) | VAF 27/94 reads (29%) | catalogued as COSV54085802, COSV99699261; called by muse, mutect2, varscan2
- ACYP1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as rs371773175; called by muse, mutect2, varscan2
- AL669918.1 | c.2054A>T p.K685M | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.232); catalogued as COSV71270868; called by muse, mutect2, varscan2
- ALDH16A1 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.327); catalogued as rs1271033907, COSV99513017; called by mutect2, varscan2
- ALPL | c.1523C>A p.A508E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV66375961; called by muse, mutect2, varscan2
- ANGPTL6 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1208309284, COSV53461425; called by muse, mutect2, varscan2
- APOA5 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV57062191, COSV57062406; called by muse, mutect2, varscan2
- APOB | c.5717C>T p.T1906I | Missense Mutation (SNP) | VAF 83/138 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs767547869, COSV51924792; called by muse, mutect2, varscan2
- ARHGEF6 | c.221T>A p.L74Q | Missense Mutation (SNP) | VAF 114/139 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV51687807; called by muse, mutect2, varscan2
- ARID4B | c.1761G>T p.M587I | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT tolerated (0.9); PolyPhen benign (0.096); catalogued as COSV51598839; called by muse, mutect2, varscan2
- ASAP1 | c.1192G>T p.A398S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63044917; called by muse, mutect2, varscan2
- ATG13 | c.453A>C p.L151F | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.354); catalogued as COSV56317667; called by muse, mutect2, varscan2
- ATG2B | c.1468+2T>A p.X490_splice | Splice Site (SNP) | VAF 24/77 reads (31%) | catalogued as COSV63421858; called by muse, mutect2, varscan2
- ATP10B | c.3336G>C p.M1112I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV59144483; called by muse, mutect2, varscan2
- ATP2A3 | c.2490T>G p.S830R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV59226526; called by muse, mutect2, varscan2
- ATXN2 | c.947G>A p.S316N (on ENST00000550104; = p.S156N on NM_002973.4) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV66481496; called by muse, mutect2, varscan2
- AURKB | c.864G>A p.V288= | Splice Region (SNP) | VAF 9/27 reads (33%) | catalogued as rs1437061929, COSV60243602; called by muse, mutect2, varscan2
- BAIAP3 | c.2309G>T p.G770V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV50103594; called by muse, mutect2, varscan2
- BMP8B | c.754T>C p.F252L | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV59593268; called by muse, mutect2, varscan2
- BPTF | c.1484G>C p.S495T | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV58832083; called by muse, mutect2, varscan2
- BRINP2 | c.1924G>C p.V642L | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs1461000407, COSV64175660; called by muse, mutect2, varscan2
- BTG4 | c.520T>G p.L174V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV63635280; called by muse, mutect2, varscan2
- BUB1 | c.2120T>G p.I707S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV57061426; called by muse, mutect2, varscan2
- CACNA1A | c.1912G>T p.G638C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64190760, COSV64206769; called by muse, mutect2, varscan2
- CCDC138 | c.1079T>A p.V360D | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV54564590; called by muse, mutect2, varscan2
- CCDC88C | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV66234532; called by muse, mutect2, varscan2
- CCNDBP1 | c.615G>T p.L205F | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV55746426; called by muse, mutect2, varscan2
- CCR9 | c.977G>A p.R326Q (on ENST00000357632 / NM_031200.3; = p.R314Q on NM_006641.4) | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.74); PolyPhen benign (0.044); catalogued as rs201410158, COSV100591752, COSV62939882; called by muse, mutect2, varscan2
- CDH26 | c.792T>G p.D264E | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.196); catalogued as COSV54843246; called by muse, mutect2, varscan2
- CDX4 | c.464G>C p.S155T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.663); catalogued as COSV65171459, COSV65171764; called by muse, mutect2, varscan2
- CEP131 | c.320G>C p.S107T | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as COSV53950961; called by muse, mutect2, varscan2
- CEP170 | c.4729G>A p.E1577K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.043); catalogued as COSV60506571; called by muse, mutect2, varscan2
- CFH | c.1308G>C p.W436C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62776396; called by muse, mutect2, varscan2
- CNTNAP2 | c.1757G>A p.S586N | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1554490567, COSV62149115; called by muse, mutect2, varscan2
- COL4A4 | c.3586G>T p.D1196Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV100307689; called by muse, mutect2, varscan2
- COP1 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 59/99 reads (60%) | catalogued as COSV58163635; called by muse, mutect2, varscan2
- CPLX3 | c.459G>T p.E153D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV59000750; called by muse, mutect2, varscan2
- CPT1A | c.90A>T p.Q30H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.717); catalogued as COSV55753227, COSV55756704; called by muse, mutect2, varscan2
- CRY2 | c.1165C>T p.L389F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69888124; called by muse, mutect2, varscan2
- CRYBB1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 62/77 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745344551, COSV53232570; called by muse, mutect2, varscan2
- CTAGE6 | c.1247T>C p.L416P | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV101417881; called by muse, mutect2
- CUTC | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV65081514; called by muse, mutect2, varscan2
- CWF19L2 | c.2669A>T p.K890I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56509347; called by muse, mutect2, varscan2
- CYP27A1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.148); catalogued as COSV51467151; called by muse, mutect2, varscan2
- CYP4F3 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV55407418; called by muse, mutect2, varscan2
- DACH2 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 68/93 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64162737; called by muse, mutect2, varscan2
- DDX23 | c.1871C>G p.P624R | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56397371; called by muse, mutect2, varscan2
- DDX5 | c.1809G>A p.M603I | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV56748067; called by muse, mutect2, varscan2
- DENND2C | c.2548G>T p.E850* (on ENST00000393274 / NM_001256404.2; = p.E793* on NM_198459.4) | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV67920177; called by muse, mutect2, varscan2
- DIAPH3 | c.1906C>G p.P636A (on ENST00000400324 / NM_001042517.2; = p.P373A on NM_030932.3) | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV57365434; called by muse, mutect2, varscan2
- DIRAS3 | c.551C>G p.T184S | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.07); catalogued as COSV63970482; called by muse, mutect2, varscan2
- DNAH11 | c.7558G>T p.V2520L | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV60941749; called by muse, mutect2, varscan2
- DNAJC19 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62798324; called by muse, mutect2, varscan2
- DNAJC5 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs887921248, COSV62670960; called by muse, mutect2, varscan2
- DNM2 | c.736A>T p.K246* | Nonsense Mutation (SNP) | VAF 29/86 reads (34%) | catalogued as rs1555707649, COSV58957510; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK10 | c.5642C>T p.A1881V | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV51350369; called by muse, mutect2, varscan2
- DOCK11 | c.2981A>T p.Y994F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV52234317, COSV52245155; called by muse, mutect2, varscan2
- DSCAML1 | c.6245G>A p.G2082D (on ENST00000321322; = p.G2022D on NM_020693.4) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.826); catalogued as rs777321533, COSV58382741; called by muse, mutect2, varscan2
- EN2 | c.700A>G p.K234E | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV52082769; called by muse, mutect2, varscan2
- EPHA3 | c.1730A>T p.D577V | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV60695522; called by muse, mutect2, varscan2
- EPHA8 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1394031937, COSV51263170; called by muse, mutect2, varscan2
- EPHB6 | c.1971G>T p.Q657H | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV63890720; called by muse, mutect2, varscan2
- EPPK1 | c.3529G>C p.A1177P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as COSV73260868; called by muse, mutect2
- ERC2 | c.922C>A p.L308I | Missense Mutation (SNP) | VAF 140/429 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55603575; called by muse, mutect2, varscan2
- EVX2 | c.523A>T p.S175C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV57962586; called by muse, mutect2
- EXD1 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 64/107 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs758861605, COSV59252931; called by muse, mutect2, varscan2
- EZH2 | c.128G>T p.S43I | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.21); PolyPhen benign (0.061); catalogued as COSV57447215; called by muse, mutect2, varscan2
- FAT1 | c.4679C>G p.P1560R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374571513, COSV71672139; called by muse, mutect2, varscan2
- FBN3 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs766315700, COSV54454291; called by muse, mutect2, varscan2
- FGF17 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV63925342; called by muse, mutect2, varscan2
- FOXG1 | c.947T>C p.L316P | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV57395407; called by muse, mutect2, varscan2
- FSCN1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61017031; called by muse, mutect2, varscan2
- FUNDC2 | c.544G>C p.G182R | Missense Mutation (SNP) | VAF 232/269 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV65670463; called by muse, mutect2, varscan2
- GABBR1 | c.2308C>T p.L770F | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63541033; called by muse, mutect2, varscan2
- GATA5 | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as COSV99436100; called by muse, mutect2
- GDF6 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54623032; called by muse, mutect2, varscan2
- GEMIN2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV51627346; called by muse, mutect2, varscan2
- GFRA2 | c.1121A>T p.Q374L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV60777819, COSV60782552; called by muse, mutect2, varscan2
- GIN1 | c.909T>A p.H303Q | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV67536050; called by muse, mutect2, varscan2
- GOLGB1 | c.1573A>C p.S525R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.086); catalogued as COSV61462203; called by muse, mutect2, varscan2
- GREB1 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV52181531; called by muse, mutect2, varscan2
- GUK1 | c.121A>G p.R41G | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57155014; called by muse, mutect2, varscan2
- GZMB | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs757031846, COSV53540212; called by muse, mutect2, varscan2
- GZMK | c.458G>A p.G153D | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50244220; called by muse, mutect2, varscan2
- HEATR6 | c.2842A>C p.T948P | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV51743918; called by muse, mutect2, varscan2
- HIGD1B | c.235G>C p.G79R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53655207, COSV53656525; called by muse, mutect2, varscan2
- HLA-E | c.737C>G p.T246S | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV64927254; called by muse, mutect2, varscan2
- HNRNPCL1 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs1255866620, COSV58610226; called by muse, mutect2, varscan2
- IFI16 | c.114A>T p.K38N | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV55531442; called by muse, mutect2, varscan2
- IMMT | c.2047G>C p.E683Q | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV54478528; called by muse, mutect2, varscan2
- INTS6L | c.1915A>T p.T639S | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV66083740; called by muse, mutect2, varscan2
- IPO8 | c.381G>A p.W127* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as COSV56239823; called by muse, mutect2, varscan2
- ITPR3 | c.5288G>C p.G1763A | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV65406170; called by muse, mutect2, varscan2
- KCNC2 | c.1095T>A p.F365L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV54363379; called by muse, mutect2, varscan2
- KDM4C | c.2942A>T p.E981V | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV67183958; called by muse, mutect2, varscan2
- KIAA1549 | c.4216C>T p.R1406C | Missense Mutation (SNP) | VAF 91/120 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776957854, COSV54306746, COSV54315244; called by muse, mutect2, varscan2
- KIF18B | c.2227G>C p.D743H (on ENST00000593135 / NM_001265577.2; = p.D755H on NM_001264573.2) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV59271015; called by muse, mutect2
- KIF2B | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs1229299890, COSV52127464; called by muse, mutect2, varscan2
- KMT5B | c.334C>A p.H112N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV58564009; called by muse, mutect2
- LARP1B | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.766); catalogued as rs747451335, COSV52794837; called by muse, mutect2, varscan2
- LARP6 | c.1427A>C p.D476A | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54579088; called by muse, mutect2, varscan2
- LATS1 | c.3256G>T p.D1086Y | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53586544; called by muse, mutect2
- LCN15 | c.62A>T p.E21V | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV60209364; called by muse, mutect2, varscan2
- LHFPL3 | c.372C>A p.Y124* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as COSV67806147; called by muse, mutect2, varscan2
- LRP3 | c.2078G>T p.C693F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as COSV53502579; called by muse, mutect2, varscan2
- LYPLAL1 | c.241T>C p.F81L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV65106318; called by muse, mutect2, varscan2
- LYST | c.10192C>T p.R3398* | Nonsense Mutation (SNP) | VAF 56/222 reads (25%) | catalogued as rs1451596846, COSV67703719; called by muse, mutect2, varscan2
- MAGEB16 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as rs761211559, COSV67873575; called by muse, mutect2, varscan2
- MAP3K20 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV64377318; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1960A>C p.N654H | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs1231819368, COSV53796825; called by muse, mutect2, varscan2
- MARVELD3 | c.941C>A p.A314E | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV51704066, COSV51705229; called by muse, mutect2, varscan2
- MAST1 | c.3544G>C p.G1182R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52241663; called by mutect2, varscan2
- MMD2 | c.589G>A p.A197T (on ENST00000404774 / NM_001100600.2; = p.A173T on NM_198403.4) | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs369477170; called by muse, mutect2, varscan2
- MPP1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV65728028, COSV65728091; called by muse, mutect2, varscan2
- MSTN | c.565A>T p.I189F | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV53620347; called by muse, mutect2, varscan2
- NALCN | c.4443A>T p.R1481S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV51920172; called by muse, mutect2, varscan2
- NCR3 | c.596C>A p.P199Q | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.202); catalogued as COSV53000479, COSV53000675; called by mutect2, varscan2
- NEFM | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55330634; called by muse, mutect2, varscan2
- NEURL1 | c.1383C>A p.C461* | Nonsense Mutation (SNP) | VAF 46/74 reads (62%) | catalogued as COSV63507996; called by muse, mutect2, varscan2
- NFASC | c.1791G>C p.E597D (on ENST00000339876 / NM_001378329.1; = p.E608D on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV58359645; called by muse, mutect2, varscan2
- NISCH | c.4019A>T p.E1340V | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV58732625; called by muse, mutect2, varscan2
- NKX3-2 | c.741G>C p.E247D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66711503; called by muse, mutect2, varscan2
- NLRP8 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV52583825; called by muse, mutect2, varscan2
- NOC2L | c.1531G>A p.V511I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.076); catalogued as rs1290893907, COSV58986139; called by muse, mutect2, varscan2
- NOTCH2 | c.3374T>G p.V1125G | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV56683049; called by muse, mutect2, varscan2
- NPAS3 | c.2061C>A p.S687R (on ENST00000356141 / NM_001164749.2; = p.S655R on NM_022123.3) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV60823356; called by muse, mutect2, varscan2
- OR5A1 | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs776326860, COSV100118368, COSV57375917; called by muse, mutect2, varscan2
- OR5M8 | c.890A>T p.K297I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV59115809; called by muse, mutect2, varscan2
- OSBPL2 | c.873-1G>A p.X291_splice (on ENST00000313733 / NM_144498.4; = p.X279_splice on NM_014835.4) | Splice Site (SNP) | VAF 22/187 reads (12%) | catalogued as COSV58215339; called by muse, mutect2, varscan2
- PCDHA1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.812); catalogued as COSV65372460, COSV65376044, COSV65376866; called by muse, mutect2, varscan2
- PCDHB15 | c.1663A>C p.N555H | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV50860245; called by muse, mutect2, varscan2
- PCID2 | c.860+1G>T p.X287_splice | Splice Site (SNP) | VAF 96/230 reads (42%) | catalogued as COSV55812983; called by muse, mutect2, varscan2
- PCLO | c.11567C>G p.P3856R | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775679251, COSV61617878; called by muse, mutect2, varscan2
- PDE4DIP | c.3215A>T p.E1072V | Missense Mutation (SNP) | VAF 50/321 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57678975; called by muse, mutect2, varscan2
- PDZD8 | c.2742A>C p.L914F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV53688679; called by muse, mutect2, varscan2
- PFKFB4 | c.499G>C p.A167P | Missense Mutation (SNP) | VAF 23/57 reads (40%) | PolyPhen possibly damaging (0.534); catalogued as COSV51679829; called by muse, mutect2, varscan2
- PIGA | c.1129A>T p.I377F | Missense Mutation (SNP) | VAF 102/131 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.298); catalogued as COSV61237007; called by muse, mutect2, varscan2
- PINK1 | c.1151A>G p.D384G | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV58630490; called by muse, mutect2, varscan2
- PLEKHM3 | c.1973C>G p.P658R | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV66815674; called by muse, mutect2, varscan2
- PLOD3 | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 11/96 reads (11%) | catalogued as COSV56181428; called by muse, mutect2, varscan2
- PLSCR2 | c.437G>A p.R146K (on ENST00000497985 / NM_001199978.1; = p.R73K on NM_020359.2) | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV60859789; called by muse, mutect2, varscan2
- PLXNB1 | c.4368C>G p.D1456E | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.213); catalogued as COSV56486957; called by muse, mutect2, varscan2
- POMZP3 | c.122C>G p.P41R | Missense Mutation (SNP) | VAF 50/333 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV51885557; called by muse, mutect2, varscan2
- PRAG1 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV58157815; called by muse, mutect2, varscan2
- PRKCG | c.568G>C p.G190R | Missense Mutation (SNP) | VAF 86/145 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54724372, COSV54728890; called by muse, mutect2, varscan2
- PRSS35 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758536096, COSV63800147; called by muse, mutect2, varscan2
- PTPRS | c.4784G>A p.R1595H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1385628370, COSV53611221; called by muse, mutect2, varscan2
- RAPGEF4 | c.866T>A p.F289Y | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51379983; called by muse, mutect2
- RAVER2 | c.787-1G>C p.X263_splice | Splice Site (SNP) | VAF 40/107 reads (37%) | catalogued as COSV53805211; called by muse, mutect2, varscan2
- RBM43 | c.436C>G p.P146A | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV58878201, COSV58879980; called by muse, mutect2, varscan2
- RECK | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.112); catalogued as COSV65034727; called by muse, mutect2, varscan2
- RFTN2 | c.729C>G p.N243K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.058); catalogued as COSV54386159; called by muse, mutect2, varscan2
- RHOBTB1 | c.1991A>C p.Q664P | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV61957840; called by muse, mutect2, varscan2
- RNF139 | c.1730A>G p.Y577C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369632760, COSV52680703; called by muse, mutect2, varscan2
- RTN1 | c.386A>G p.K129R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.321); catalogued as COSV50719158; called by muse, mutect2, varscan2
- RUNDC3A | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV56586477; called by muse, mutect2, varscan2
- RYR1 | c.13882A>T p.M4628L | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV62090194; called by muse, mutect2, varscan2
- SAMD9L | c.1898G>A p.R633K | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV59079852; called by muse, mutect2, varscan2
- SCN3A | c.5404C>T p.P1802S | Missense Mutation (SNP) | VAF 89/154 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as COSV51802438; called by muse, mutect2, varscan2
- SEC31A | c.2768C>A p.S923Y (on ENST00000355196 / NM_001318120.1; = p.S884Y on NM_016211.4) | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV52341873; called by muse, mutect2, varscan2
- SLC10A3 | c.119G>A p.W40* | Nonsense Mutation (SNP) | VAF 42/104 reads (40%) | catalogued as COSV54835649, COSV99682213; called by muse, mutect2, varscan2
- SLC12A7 | c.1698G>C p.E566D | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV53754832; called by muse, mutect2, varscan2
- SLC16A1 | c.1235T>A p.L412H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63708636; called by muse, mutect2, varscan2
- SLC16A9 | c.259T>G p.F87V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.112); catalogued as COSV68098358; called by muse, mutect2, varscan2
- SLC22A9 | c.760G>C p.A254P | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54165992; called by muse, mutect2, varscan2
- SLC38A10 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV104385690, COSV55842250; called by muse, mutect2, varscan2
- SLC6A4 | c.1388A>G p.E463G | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55565235; called by muse, mutect2, varscan2
- SLITRK6 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as COSV68389464; called by muse, mutect2, varscan2
- SNCAIP | c.58-2A>C p.X20_splice | Splice Site (SNP) | VAF 55/151 reads (36%) | catalogued as COSV54403001; called by muse, mutect2, varscan2
- SPEN | c.9008C>T p.S3003L | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1386910185, COSV65358324; called by muse, mutect2, varscan2
- SPNS2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 73/93 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as rs768890918, COSV61229309; called by muse, mutect2, varscan2
- SPTBN5 | c.3005T>C p.V1002A | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV58016993; called by muse, mutect2, varscan2
- STRC | c.4875T>A p.H1625Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV55851894; called by muse, mutect2, varscan2
- SYNE1 | c.12797C>T p.S4266F (on ENST00000367255 / NM_182961.4; = p.S4195F on NM_033071.3) | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV54916564; called by muse, mutect2, varscan2
- TACC2 | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 95/296 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as COSV57747456, COSV57756722; called by muse, mutect2, varscan2
- TAF1 | c.3596A>G p.E1199G (on ENST00000373790 / NM_138923.4; = p.E1220G on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52108178; called by muse, mutect2, varscan2
- TAS2R4 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.257); catalogued as COSV56093257; called by muse, mutect2, varscan2
- TBC1D4 | c.151A>G p.T51A | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs370400049; called by muse, mutect2, varscan2
- TEDC1 | c.586-1G>C p.X196_splice | Splice Site (SNP) | VAF 12/33 reads (36%) | catalogued as COSV58153142; called by muse, mutect2, varscan2
- TGM7 | c.1415C>G p.A472G | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV71772596; called by muse, mutect2, varscan2
- TLN1 | c.1463T>C p.L488P | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.717); catalogued as COSV59204545; called by muse, mutect2, varscan2
- TNFSF13B | c.112T>G p.S38A | Missense Mutation (SNP) | VAF 51/533 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV65515804; called by muse, mutect2
- TNS4 | c.445A>T p.K149* | Nonsense Mutation (SNP) | VAF 49/86 reads (57%) | catalogued as COSV54183514; called by muse, mutect2, varscan2
- TP53TG5 | c.685T>C p.S229P | Missense Mutation (SNP) | VAF 97/242 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV65576996, COSV65578259; called by muse, mutect2, varscan2
- TPH2 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs911612184, COSV61590724; called by muse, mutect2, varscan2
- TRPV6 | c.1016C>T p.T339I | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1379470524, COSV63890722; called by muse, mutect2
- UBR4 | c.11992C>T p.L3998F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64383394; called by muse, mutect2, varscan2
- UROC1 | c.1455G>T p.K485N | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV52030233; called by muse, mutect2, varscan2
- USP25 | c.580A>G p.R194G | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs747400380, COSV53481593; called by muse, mutect2, varscan2
- USP34 | c.6187T>G p.S2063A | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV68398571; called by muse, mutect2, varscan2
- UTP18 | c.879G>C p.L293F | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV56582332; called by muse, mutect2, varscan2
- VGLL3 | c.857C>A p.T286K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV67352469; called by muse, varscan2
- VIP | c.61T>A p.S21T | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV100923943, COSV65888536; called by muse, mutect2, varscan2
- WLS | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); catalogued as rs373658553; called by muse, mutect2, varscan2
- WNT11 | c.962A>G p.Y321C | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV59443120; called by muse, mutect2, varscan2
- XDH | c.1901G>A p.C634Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.332); catalogued as COSV65147136; called by muse, mutect2, varscan2
- XKR4 | c.1874G>A p.C625Y | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs756130370, COSV59301026; called by muse, mutect2, varscan2
- XRN1 | c.1540C>A p.L514I | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV53808349; called by muse, mutect2, varscan2
- ZDBF2 | c.3547G>T p.E1183* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as COSV65622459; called by muse, mutect2, varscan2
- ZDHHC5 | c.515T>A p.L172H | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54705215; called by muse, mutect2, varscan2
- ZDHHC8 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 19/133 reads (14%) | catalogued as rs1271230721, COSV57709047; called by muse, mutect2, varscan2
- ZMAT1 | c.1561C>G p.L521V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV65657826; called by muse, mutect2, varscan2
- ZNF140 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 78/243 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV104409914; called by muse, mutect2, varscan2
- ZNF530 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60530948; called by muse, mutect2, varscan2
- ZNF536 | c.2508C>A p.D836E | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV62819287; called by muse, mutect2, varscan2
- ZNF626 | c.338T>A p.L113* | Nonsense Mutation (SNP) | VAF 18/99 reads (18%) | catalogued as COSV74129010; called by muse, mutect2, varscan2
- ZNF705A | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 90/148 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.16); catalogued as COSV63732856; called by muse, mutect2, varscan2
- ZNF93 | c.1679C>A p.T560N | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV59374214; called by muse, mutect2, varscan2
- AGER | c.1160_1170del p.E387Vfs*5 | Frame Shift Del (DEL) | VAF 125/367 reads (34%) | called by mutect2, pindel, varscan2
- ALDH16A1 | c.769del p.A257Pfs*25 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | called by mutect2, varscan2
- ANKRD11 | c.403del p.T135Qfs*27 | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | called by mutect2, pindel, varscan2
- B3GAT2 | c.888_893del p.L297_V298del | In Frame Del (DEL) | VAF 27/70 reads (39%) | called by mutect2, pindel, varscan2
- CARMIL2 | c.2767del p.E923Nfs*146 | Frame Shift Del (DEL) | VAF 47/105 reads (45%) | called by mutect2, pindel, varscan2
- CCDC47 | c.1228_1248del p.R410_N416del | In Frame Del (DEL) | VAF 26/127 reads (20%) | called by mutect2, pindel
- CSMD2 | c.1852_1863del p.L618_N621del | In Frame Del (DEL) | VAF 33/102 reads (32%) | called by mutect2, pindel, varscan2
- DPH7 | c.549del p.R184Gfs*37 | Frame Shift Del (DEL) | VAF 55/187 reads (29%) | called by mutect2, pindel, varscan2
- FER1L6 | c.1570_1591del p.S524Tfs*32 | Frame Shift Del (DEL) | VAF 43/134 reads (32%) | called by mutect2, pindel
- HECTD1 | c.1673_1687del p.A558_E562del | In Frame Del (DEL) | VAF 23/112 reads (21%) | called by mutect2, pindel, varscan2
- HGS | c.1914_1944del p.A639Rfs*67 | Frame Shift Del (DEL) | VAF 29/181 reads (16%) | called by mutect2, pindel
- MAP2K4 | c.657_668del p.E221_K224del | In Frame Del (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- MTPAP | c.152_157+25del p.X51_splice | Splice Site (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel
- NAV1 | c.5617del p.L1873Ffs*66 | Frame Shift Del (DEL) | VAF 15/93 reads (16%) | called by mutect2, pindel, varscan2
- PRAMEF2 | c.1020_1028del p.G341_L343del | In Frame Del (DEL) | VAF 36/280 reads (13%) | called by pindel, varscan2
- RPS21 | c.133_168del p.R45_C56del | In Frame Del (DEL) | VAF 25/245 reads (10%) | called by mutect2, pindel
- SHTN1 | c.333_380del p.V112_D127del | In Frame Del (DEL) | VAF 22/60 reads (37%) | called by mutect2, pindel
- TCP11 | c.1029_1043del p.F343_V347del (on ENST00000512012; = p.F281_V285del on NM_018679.5) | In Frame Del (DEL) | VAF 30/87 reads (34%) | called by mutect2, pindel, varscan2
- THRA | c.489_502del p.E163Dfs*28 | Frame Shift Del (DEL) | VAF 27/139 reads (19%) | called by pindel, varscan2
- TMEM132A | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.143); called by muse, mutect2
- TOX | c.777_787del p.N259Kfs*12 | Frame Shift Del (DEL) | VAF 23/120 reads (19%) | called by mutect2, pindel, varscan2
- TRAV8-6 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ALDH1A2 | c.159A>G p.R53= | Silent (SNP) | VAF 52/139 reads (37%) | catalogued as COSV51078388; called by muse, mutect2, varscan2
- ALOX5 | c.1407C>T p.Y469= | Silent (SNP) | VAF 59/320 reads (18%) | catalogued as COSV65551200; called by muse, mutect2, varscan2
- AP001781.2 | c.58C>T p.L20= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV52786816; called by muse, mutect2, varscan2
- ATP13A5 | c.3567C>T p.N1189= | Silent (SNP) | VAF 43/223 reads (19%) | catalogued as rs776685790, COSV53230223; called by muse, mutect2, varscan2
- AXIN2 | c.591C>G p.L197= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as COSV61055823; called by muse, mutect2, varscan2
- BACH2 | c.756T>G p.G252= | Silent (SNP) | VAF 72/119 reads (61%) | catalogued as COSV57585381; called by muse, mutect2, varscan2
- BSX | c.657C>T p.D219= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV58005106; called by muse, mutect2, varscan2
- CACNA1C | c.5907C>T p.S1969= (on ENST00000399634 / NM_001167625.1; = p.S1898= on NM_000719.7) | Silent (SNP) | VAF 56/182 reads (31%) | catalogued as COSV59699205; called by muse, mutect2, varscan2
- CACNA1I | c.1887G>A p.T629= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs371390627; called by muse, mutect2
- CACTIN | c.1734G>T p.P578= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV50266851; called by muse, mutect2, varscan2
- CHD3 | c.432G>T p.L144= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as COSV57872828; called by muse, mutect2, varscan2
- CHKB | c.726C>T p.D242= | Silent (SNP) | VAF 173/235 reads (74%) | catalogued as COSV56415245; called by muse, mutect2, varscan2
- CHST3 | c.834G>T p.R278= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100910522; called by muse, mutect2, varscan2
- CILK1 | c.87G>T p.L29= | Silent (SNP) | VAF 52/174 reads (30%) | catalogued as COSV100607785, COSV63153533, COSV63155120; called by muse, mutect2, varscan2
- CWH43 | c.1899G>C p.L633= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV56936382, COSV56939399; called by muse, mutect2, varscan2
- DAPK2 | c.1065C>T p.I355= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs939539718, COSV56043956; called by muse, mutect2, varscan2
- DAPK3 | c.57G>A p.L19= | Silent (SNP) | VAF 34/65 reads (52%) | catalogued as COSV56662248, COSV56662530; called by muse, mutect2, varscan2
- DBT | c.538C>T p.L180= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as COSV64494969; called by muse, mutect2, varscan2
- DEFB110 | c.66T>C p.N22= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV67017872; called by muse, mutect2, varscan2
- DSP | c.2334C>A p.L778= | Silent (SNP) | VAF 53/228 reads (23%) | catalogued as COSV65791419; called by muse, mutect2, varscan2
- DUSP22 | c.124A>C p.R42= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV60524021; called by muse, mutect2, varscan2
- EIF5B | c.276C>G p.T92= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV56811297; called by muse, mutect2, varscan2
- FAM47B | c.1752C>T p.D584= | Silent (SNP) | VAF 99/135 reads (73%) | catalogued as COSV61452643; called by muse, mutect2, varscan2
- FBXO46 | c.1305C>T p.D435= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV58347889; called by muse, mutect2, varscan2
- FGL2 | c.465T>C p.H155= | Silent (SNP) | VAF 66/113 reads (58%) | catalogued as COSV50380309; called by muse, mutect2, varscan2
- HDAC9 | c.1318T>C p.L440= | Silent (SNP) | VAF 56/143 reads (39%) | catalogued as COSV67767861; called by muse, mutect2, varscan2
- HPS4 | c.2058G>A p.Q686= | Silent (SNP) | VAF 44/268 reads (16%) | catalogued as COSV61102643; called by muse, mutect2, varscan2
- KRT73 | c.942C>G p.A314= | Silent (SNP) | VAF 45/76 reads (59%) | catalogued as COSV59838048; called by muse, mutect2, varscan2
- KRT9 | c.48G>A p.G16= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV55851637; called by muse, mutect2, varscan2
- MCF2L | c.1887C>T p.A629= (on ENST00000375608; = p.A597= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV65048653; called by muse, mutect2, varscan2
- MOCS1 | c.84C>A p.T28= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100418835; called by muse, varscan2
- MYOM3 | c.1977A>G p.T659= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV58390335; called by muse, mutect2, varscan2
- NLRP1 | c.2814C>T p.G938= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs772089891, COSV52559344; called by muse, mutect2, varscan2
- NPTX2 | c.963C>A p.G321= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV55716260; called by muse, mutect2, varscan2
- NPY2R | c.679T>C p.L227= | Silent (SNP) | VAF 55/85 reads (65%) | catalogued as rs149843372; called by muse, mutect2, varscan2
- OR6M1 | c.246C>T p.C82= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as COSV58432864; called by muse, mutect2, varscan2
- ORC2 | c.16T>C p.L6= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV52237292; called by muse, mutect2, varscan2
- PAMR1 | c.531C>T p.C177= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as COSV53509970; called by muse, mutect2, varscan2
- PCLO | c.4851A>C p.T1617= | Silent (SNP) | VAF 60/255 reads (24%) | catalogued as COSV61617889; called by muse, mutect2, varscan2
- PKHD1L1 | c.8682T>C p.N2894= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV65738129; called by muse, mutect2, varscan2
- PKM | c.1125G>A p.V375= | Silent (SNP) | VAF 46/76 reads (61%) | catalogued as COSV58787113; called by muse, mutect2, varscan2
- POGZ | c.3117C>T p.R1039= | Silent (SNP) | VAF 20/202 reads (10%) | catalogued as rs371361212; ClinVar: likely benign; called by muse, mutect2, varscan2
- RALGAPA2 | c.5448C>T p.I1816= | Silent (SNP) | VAF 45/62 reads (73%) | catalogued as COSV52489361; called by muse, mutect2, varscan2
- RC3H1 | c.2847A>G p.S949= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as COSV51198003; called by muse, mutect2, varscan2
- SEZ6L2 | c.1821C>T p.S607= (on ENST00000308713 / NM_001114099.3; = p.S537= on NM_012410.4) | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as rs371152293, COSV58097442; called by muse, mutect2, varscan2
- SHANK3 | c.1647C>T p.Y549= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs767613899, COSV99437996; called by muse, mutect2, varscan2
- STRN4 | c.1161C>T p.F387= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV54416393; called by muse, mutect2, varscan2
- STX4 | c.612G>A p.S204= | Silent (SNP) | VAF 33/48 reads (69%) | catalogued as rs114513418, COSV58267907; called by muse, mutect2, varscan2
- TAF5L | c.1044G>C p.T348= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as rs757142769, COSV51077509, COSV51079820; called by muse, mutect2, varscan2
- TCEAL3 | c.303G>A p.P101= | Silent (SNP) | VAF 157/184 reads (85%) | catalogued as COSV54580134; called by muse, mutect2, varscan2
- TDRD10 | c.42G>C p.L14= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs757151932, COSV63811403; called by muse, mutect2, varscan2
- TECTA | c.1893C>T p.C631= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV50689364; called by muse, mutect2, varscan2
- TMPPE | c.1266C>T p.F422= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs758668019, COSV56561620; called by muse, mutect2, varscan2
- TRMT61A | c.312C>A p.G104= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV54568536; called by muse, mutect2, varscan2
- TTC27 | c.1701C>G p.L567= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV58649157, COSV58656802; called by muse, mutect2, varscan2
- TULP4 | c.2716C>A p.R906= | Silent (SNP) | VAF 53/193 reads (27%) | catalogued as COSV100893942, COSV65572530; called by muse, mutect2, varscan2
- BTBD7 | c.1162+5163T>G | Intron (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100108214; called by muse, mutect2, varscan2
- FAM83A | c.*1810C>A | 3'UTR (SNP) | VAF 22/69 reads (32%) | catalogued as COSV99414609; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.715C>T | RNA (SNP) | VAF 31/155 reads (20%) | catalogued as rs782500275; called by muse, mutect2, varscan2
- PRR12 | c.51+99G>A | Intron (SNP) | VAF 16/48 reads (33%) | catalogued as rs767028330, COSV55869573; called by muse, mutect2, varscan2
- ZNF271P | n.1755G>T | RNA (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- ZNF467 | chr7:149776949 G>C | 5'Flank (SNP) | VAF 15/78 reads (19%) | catalogued as COSV50486556, COSV50489662; called by muse, mutect2, varscan2
